Gene-level copy-number profile of tumor specimen C3L-07972-02 from CPTAC case C3L-07972, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G3; Age at diagnosis: 63.9 years (23,347 days).
Specimen C3L-07972-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Antrum; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 35e4463d-b1dd-44f2-8271-3f9bf95bef1c.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-07972-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,719 have no estimate.
https://portal.gdc.cancer.gov/files/e275cdff-9ed0-4571-9fee-dd7187b50ad9

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 20,787; copy number 2: 31,047; copy number 3: 5,724; copy number 4: 354; copy number 5: 201; copy number 6: 375; copy number 7: 180; copy number 8: 55; copy number 9: 12; copy number 10: 15; copy number 11: 52; copy number 12: 1; copy number 14: 35; copy number 17: 7; copy number 20: 11; copy number 24: 8; copy number 25: 8; copy number 28: 32.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 992 genes in 27 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:88,205,115–88,306,894, 4 genes, copy number 6: SRI, SRI-AS1, AC003991.1, STEAP4.
- chr7:90,466,424–91,210,590, 1 gene, copy number 17 (within-gene range 2–17): CDK14.
- chr7:91,030,149–94,801,812, 64 genes, copy number 14–28 (broad region; genes not listed).
- chr9:41,890,314–42,129,510, 1 gene, copy number 6 (within-gene range 1–6): CNTNAP3B.
- chr9:42,011,350–43,045,120, 24 genes, copy number 6–7: RN7SL343P, SPATA31A6, AL445584.1, FAM74A7, AL445584.3, AL445584.2, FKBP4P6, SDR42E1P2, ATP5F1AP1, RAB28P3, RBPJP6, BX088651.4, BX088651.1, BX088651.2, FGF7P5, BX088651.3, FGF7P4, BX664718.1, BX664718.2, ADGRF5P2, MEP1AP4, RNU6-599P, CNN2P4, AL591441.1.
- chr9:64,439,346–64,637,586, 8 genes, copy number 6–8: SNX18P9, CR769776.2, CYP4F25P, CR769776.1, CNN2P3, GXYLT1P6, AL773524.1, AQP7P2.
- chr9:94,726,604–95,087,159, 1 gene, copy number 5 (within-gene range 4–5): AOPEP.
- chr9:94,900,429–95,086,094, 8 genes, copy number 5: AL807757.2, AL353768.1, AL353768.2, MIR6081, MIR23B, MIR27B, MIR3074, MIR24-1.
- chr9:124,001,670–124,771,311, 17 genes, copy number 5 (within-gene range 4–5): LHX2, AC006450.3, AC006450.1, AC006450.2, NEK6, AL162724.2, AL162724.1, PSMB7, ADGRD2, NR5A1, AL354979.1, NR6A1, AL669818.1, RN7SL302P, MIR181A2HG, MIR181A2, MIR181B2.
- chr9:126,805,006–127,223,166, 4 genes, copy number 6 (within-gene range 4–6): ZBTB43, ZBTB34, RALGPS1, ANGPTL2.
- chr9:136,206,333–136,687,457, 23 genes, copy number 5: QSOX2, CCDC187, CR392000.1, DKFZP434A062, GPSM1, DNLZ, CARD9, SNAPC4, ENTR1, PMPCA, INPP5E, SEC16A, C9orf163, NOTCH1, MIR4673, AL592301.1, MIR4674, NALT1, LINC01451, AL590226.1, EGFL7, MIR126, AGPAT2.
- chr9:137,174,784–137,190,370, 2 genes, copy number 6: ANAPC2, SSNA1.
- chr10:36,089,086–38,783,108, 58 genes, copy number 6–11: AL355300.1, MTND5P17, MTND4P18, AL590730.1, AL590730.2, NAMPTP1, Y_RNA, AL390061.1, MKNK2P1, ARL6IP1P2, ANKRD30A, RNU6-811P, AL157387.1, LINC00993, RN7SL314P, Y_RNA, TMEM161BP1, VN1R53P, TACC1P1, MTND1P18, MTRNR2L7, AL132657.1, ZNF248, AL132657.2, ZNF33BP1, TLK2P2, AL135791.1, ZNF37CP, ZNF33CP, ZNF25, ZNF25-DT, Y_RNA, ZNF33A, RNU6-795P, AL161931.1, EIF3LP3, FXYD6P2, ZNF37A, AL117339.4, AL117339.3, AL117339.1, CCNYL4, AL133217.1, AL117339.2, HSD17B7P2, SEPTIN7P9, AL133216.2, RNU6-1118P, CICP9, AL133216.1, ABCD1P2, AL133173.2, PABPC1P12, SLC9B1P3, ACTR3BP5, CHEK2P5, AL133173.1, AL590623.1.
- chr10:58,869,184–59,364,075, 8 genes, copy number 6: RN7SKP196, LINC00844, RPLP1P10, TRAF6P1, PHYHIPL, FAM13C, AC025038.1, AL355474.1.
- chr10:73,130,155–79,873,903, 156 genes, copy number 5–11 (within-gene range 2–11) (broad region; genes not listed).
- chr13:28,820,348–31,162,388, 42 genes, copy number 6–7: MTUS2, MTUS2-AS2, GAPDHP69, AL596092.1, MTUS2-AS1, SLC7A1, UBL3, Metazoa_SRP, TIMM8BP1, LINC00297, LINC00572, LINC00544, AL354674.1, LINC00365, LINC00384, LINC00385, AL157770.1, KATNAL1, RNU6-64P, PRDX2P1, LINC00427, LINC00426, AL356750.1, LINC01058, UBE2L5, HMGB1, AL353648.1, RBM22P2, MFAP1P1, PTPN2P2, USPL1, Metazoa_SRP, ALOX5AP, LINC00398, LINC00545, TEX26-AS1, MEDAG, TEX26, AL353680.1, LINC01066, WDR95P, HSPH1.
- chr14:42,259,731–56,310,761, 234 genes, copy number 5–6 (broad region; genes not listed).
- chr14:57,563,920–57,982,194, 2 genes, copy number 6 (within-gene range 4–6): SLC35F4, AL161804.1.
- chr14:57,837,354–61,658,696, 76 genes, copy number 5–6 (broad region; genes not listed).
- chr14:96,392,128–96,567,111, 5 genes, copy number 7: AK7, PEBP1P1, RPL23AP10, AL163051.1, PAPOLA.
- chr20:44,347,552–45,670,270, 62 genes, copy number 6–11 (within-gene range 2–11) (broad region; genes not listed).
- chr20:46,118,278–47,188,844, 23 genes, copy number 5–14 (within-gene range 1–14): CD40, AL031687.1, CDH22, SLC35C2, AL133227.1, ELMO2, ZNF663P, AL031686.1, MKRN7P, ZNF840P, ZNF334, OCSTAMP, SLC13A3, AL133520.1, TP53RK, AL031055.1, SLC2A10, RN7SKP33, AL354766.1, EYA2, AL354766.2, GAPDHP54, AL121776.1.
- chr20:48,324,812–49,729,842, 31 genes, copy number 6–10: AL121888.1, LINC00494, AL137078.1, AL137078.2, AL049541.1, AL049541.2, RNU7-144P, PREX1, AL035106.1, AL133342.1, ARFGEF2, SNAP23P1, CSE1L-AS1, CSE1L, STAU1, ARPC3P1, DDX27, ZNFX1, ZFAS1, AL049766.2, SNORD12C, AL049766.1, SNORD12B, AL049766.3, SNORD12, KCNB1, AL035685.1, PTGIS, B4GALT5, RN7SL197P, SNRPFP1.
- chr20:52,671,735–54,070,594, 21 genes, copy number 9–25 (within-gene range 4–25): AL031674.1, AL121902.1, RPL36P1, TSHZ2, RN7SKP184, AL391097.3, AL391097.1, AL391097.2, AL109930.1, AL354993.1, PPIAP10, AL354993.2, Y_RNA, AL157838.1, ZNF217, AC005808.1, RNU7-14P, AC006076.1, SUMO1P1, BCAS1, AC005220.1.
- chr20:56,205,052–56,460,387, 9 genes, copy number 8 (within-gene range 8–12): RNA5SP487, MC3R, AL139824.2, AL139824.1, FAM210B, AURKA, CSTF1, CASS4, RPL39P.
- chr20:58,097,267–60,653,784, 52 genes, copy number 7 (within-gene range 3–7): AL354984.3, C20orf85, ANKRD60, PPP4R1L, RAB22A, VAPB, APCDD1L, APCDD1L-DT, AL050327.1, LINC01711, STX16, STX16-NPEPL1, NPEPL1, AL139349.1, PIEZO1P2, AL132655.3, AL132655.2, MIR296, MIR298, GNAS-AS1, AL132655.1, GNAS, AL132655.7, AL132655.6, AL132655.4, AL132655.5, AL121917.1, AL121917.2, NELFCD, CTSZ, TUBB1, ATP5F1E, PRELID3B, MRPS16P2, ZNF831, EDN3, AL035250.1, AL035250.2, PIEZO1P1, AL389889.1, PHACTR3, PHACTR3-AS1, RNU7-141P, SYCP2, FAM217B, PPP1R3D, CDH26, C20orf197, AL132822.1, MIR646HG, MIR646, MTCO2P1.
- chr20:61,252,261–62,937,952, 56 genes, copy number 7 (within-gene range 3–7): CDH4, AL365229.1, BX640515.1, AL160412.1, AL162457.1, AL162457.2, TAF4, MIR1257, AL137077.1, MIR3195, LSM14B, PSMA7, SS18L1, MTG2, HRH3, OSBPL2, ADRM1, AL354836.1, LAMA5, MIR4758, LAMA5-AS1, AL121832.2, RPS21, CABLES2, AL121832.3, RBBP8NL, AL121832.1, GATA5, AL499627.2, AL499627.1, MIR1-1HG-AS1, MIR1-1HG, MIR1-1, MIR133A2, RPL7P3, BX640514.1, BX640514.2, AL450469.2, AL450469.1, AL357033.1, SLCO4A1, AL357033.4, AL357033.3, SLCO4A1-AS1, LINC00686, NTSR1, AL357033.2, LINC00659, MRGBP, OGFR-AS1, OGFR, COL9A3, TCFL5, DPH3P1, ARF4P2, DIDO1.

Autosomal genes at a single copy (total copy number 1): 18,140. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
